Gene-level copy-number profile of tumor specimen TCGA-24-2026-01A from TCGA case TCGA-24-2026, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IIIC; Tumor grade: G3; Age at diagnosis: 79.5 years (29,050 days).
Specimen TCGA-24-2026-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-OV.0a35f5c8-aad8-45f8-aaf2-94f16c84a273.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-24-2026-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 816 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; AscatNGS; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/9b10598e-0d92-4db6-8113-88ff430fd0b1

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 6; copy number 1: 17; copy number 2: 3,164; copy number 3: 10,458; copy number 4: 15,036; copy number 5: 10,568; copy number 6: 11,858; copy number 7: 5,302; copy number 8: 1,768; copy number 9: 973; copy number 10: 215; copy number 11: 66; copy number 12: 107; copy number 13: 17; copy number 14: 111; copy number 16: 141.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, sample TCGA-24-2026-01): tumor purity 0.76, ploidy 5.1, whole-genome doublings 2 (call status: legacy_call).

Homozygous deletions (total copy number 0; autosomes only): 3 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr16:78,525,189–78,553,296, 3 genes: AC046158.4, AC046158.2, AC046158.3.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 1,630 genes in 42 contiguous regions (the 40 largest listed; coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:9,292,894–10,895,998, 49 genes, copy number 10 (within-gene range 6–10): SPSB1, BX323043.1, LINC02606, RNA5SP40, AL928921.1, SLC25A33, AL954705.1, TMEM201, PIK3CD, PIK3CD-AS1, AL691449.1, PIK3CD-AS2, CLSTN1, MZT1P1, AL357140.3, CTNNBIP1, AL357140.1, AL357140.4, LZIC, AL357140.2, NMNAT1, RN7SKP269, TMEM274P, MIR5697, AL603962.1, RBP7, UBE4B, AL590639.1, PGAM1P11, RNU6-828P, KIF1B, AL358013.1, RNU6-37P, RN7SL731P, AL139424.3, AL139424.2, PGD, AL139424.1, CENPS-CORT, CENPS, CORT, DFFA, AL354956.1, PEX14, AL139423.2, RN7SL614P, CASZ1, AL139423.1, HSPE1P24.
- chr1:89,820,174–90,284,188, 9 genes, copy number 9: AC099568.2, LRRC8D, AL391497.1, RN7SKP272, GEMIN8P4, ZNF326, AL161797.1, AC098656.1, RNU6-695P.
- chr1:116,909,916–117,528,872, 14 genes, copy number 9 (within-gene range 7–9): PTGFRN, RNA5SP55, CD101, AL445231.1, TTF2, MIR942, TRIM45, RPS15AP9, VTCN1, Metazoa_SRP, LINC01525, AL358072.1, MAN1A2, AL157902.2.
- chr1:154,671,593–156,456,763, 102 genes, copy number 12 (within-gene range 6–12) (broad region; genes not listed).
- chr1:228,555,793–229,305,894, 33 genes, copy number 9 (within-gene range 6–9): RNA5SP19, RNA5SP162, RNA5S1, RNA5S2, RNA5S3, RNA5S4, RNA5S5, RNA5S6, RNA5S7, RNA5S8, RNA5S9, RNA5S10, RNA5S11, RNA5S12, RNA5S13, RNA5S14, RNA5S15, RNA5S16, RNA5S17, RNA5SP18, DUSP5P1, AL713899.1, FTH1P2, RHOU, AL078624.2, AL078624.1, LINC02815, ISCA1P2, LINC02814, AL162595.2, TMEM78, AL162595.1, RAB4A.
- chr2:28,448,167–28,948,219, 15 genes, copy number 10: AC104695.1, PLB1, SNRPGP7, AC074011.1, RNA5SP89, AC092164.1, PPP1CB, SPDYA, AC097724.1, TRMT61B, WDR43, SNORD92, SNORD53, Y_RNA, SNORD53B.
- chr2:28,972,414–28,972,521, 1 gene, copy number 10: Y_RNA.
- chr3:49,940,007–50,221,486, 8 genes, copy number 9: RBM6, RBM5, RBM5-AS1, SEMA3F-AS1, SEMA3F, AC104450.1, GNAT1, SLC38A3.
- chr3:112,140,898–112,294,227, 1 gene, copy number 9 (within-gene range 7–9): SLC9C1.
- chr3:112,302,478–113,184,377, 21 genes, copy number 9 (within-gene range 6–9): AC112487.1, AC112487.2, CD200, AC092894.1, BTLA, OR7E100P, AC092692.1, ATG3, SLC35A5, CCDC80, AC048334.1, LINC02042, CD200R1L-AS1, CD200R1L, CD200R1, AC074044.1, GTPBP8, NEPRO, AC078785.1, AC078785.3, AC078785.2.
- chr3:127,915,232–128,681,075, 19 genes, copy number 10: KBTBD12, RNA5SP139, SEC61A1, RUVBL1, RNU2-37P, RUVBL1-AS1, RNU6-823P, EEFSEC, AL449214.1, DNAJB8, DNAJB8-AS1, GATA2, GATA2-AS1, TMED10P2, AC080005.1, LINC01565, RPN1, Metazoa_SRP, POU5F1P6.
- chr3:141,944,428–142,723,881, 16 genes, copy number 10: TFDP2, AC133435.1, RNU6-425P, GK5, XRN1, RNU6-1294P, RNU1-100P, ATR, AC109992.1, AC109992.2, RPL6P9, RNA5SP143, PLS1, PLS1-AS1, RN7SKP25, AC072028.1.
- chr3:169,613,510–170,860,993, 39 genes, copy number 9 (within-gene range 7–9): AC007849.1, SDHDP3, RNU6-637P, TERC, Telomerase-vert, ACTRT3, AC078802.1, MYNN, AC078795.1, LRRC34, AC078795.3, AC078795.2, LRRIQ4, LRRC31, KRT18P43, SAMD7, AC008040.2, AC008040.1, AC008040.3, SEC62, SEC62-AS1, GPR160, RNU4-38P, KMT5AP3, PHC3, RNU6-315P, PRKCI, Y_RNA, AC073288.1, SKIL, AC073288.2, CLDN11, AC026316.4, MIR6828, SLC7A14-AS1, SLC7A14, KRT8P13, AC026316.1, AC026316.3.
- chr3:177,294,442–177,899,224, 10 genes, copy number 10 (within-gene range 7–10): LINC00501, ASS1P7, AC117465.1, LINC00578, RN7SKP52, AC026355.3, AC026355.1, AC026355.2, AC026355.4, LINC02015.
- chr4:2,462,220–3,243,960, 19 genes, copy number 9 (within-gene range 6–9): RNF4, AL645924.1, AL645924.2, FAM193A, CR545473.1, Y_RNA, TNIP2, SH3BP2, ADD1, AL121750.1, MFSD10, NOP14-AS1, NOP14, GRK4, HTT, RNU6-204P, HTT-AS, AL390065.2, AL390065.1.
- chr4:39,182,504–39,782,792, 22 genes, copy number 9: WDR19, RFC1, RNU6-32P, RNU6-887P, KLB, MIR5591, Y_RNA, RPL9, LIAS, AC021148.1, UGDH, UGDH-AS1, AC021148.2, SMIM14, AC108471.3, RNU7-11P, AC108471.2, UBE2K, Y_RNA, AC108471.1, RN7SL558P, ZBTB12BP.
- chr4:118,722,823–119,628,804, 18 genes, copy number 14: SEC24D, SYNPO2, AC096745.1, MYOZ2, AC092656.1, USP53, C4orf3, FABP2, KLHL2P1, RNU4-33P, AC110373.1, GTF2IP12, AC093752.3, RNU6-1217P, AC093752.1, AC093752.2, PDE5A, AC080089.1.
- chr4:145,444,899–146,521,964, 22 genes, copy number 9 (within-gene range 6–9): AC093796.1, NMNAT1P4, SMAD1, SMAD1-AS2, SMAD1-AS1, MMAA, NCOA4P3, AC093864.1, C4orf51, ZNF827, AC104791.2, AC104791.1, Y_RNA, AC108206.1, LINC01095, LSM6, AC097372.2, REELD1, AC097372.3, AC097372.1, SLC10A7, MIR7849.
- chr5:58,198–1,309,377, 48 genes, copy number 16: AC113430.1, PLEKHG4B, Y_RNA, LRRC14B, AC021087.4, CCDC127, AC021087.3, SDHA, AC021087.5, AC021087.1, PDCD6, PDCD6-AHRR, AC021087.2, AHRR, AC010442.1, AC010442.2, EXOC3-AS1, EXOC3, PP7080, SLC9A3, SLC9A3-AS1, AC106772.2, MIR4456, AC106772.1, CEP72, TPPP, AC026740.1, ZDHHC11B, BRD9P2, AC026740.2, ZDHHC11, SPCS2P3, BRD9, TRIP13, AC122719.3, AC122719.1, AC122719.2, AC116351.1, AC116351.2, NKD2, SLC12A7, MIR4635, CTD-3080P12.3, SLC6A19, SLC6A18, AC114291.1, TERT, MIR4457.
- chr5:10,057,502–10,522,084, 29 genes, copy number 9: AC091905.2, AC091905.3, AC091905.1, AC091905.4, AC034229.1, AC034229.6, AC034229.5, AC034229.2, AC034229.3, AC034229.4, ATPSCKMT, AC012640.1, CCT5, AC012640.4, AC012640.3, CMBL, Y_RNA, Y_RNA, AC012640.5, AC012640.2, MARCHF6, ROPN1L-AS1, ROPN1L, MIR6131, LINC01513, RPL30P7, AC092336.1, LINC02212, LINC02213.
- chr5:15,500,180–16,681,905, 15 genes, copy number 9 (within-gene range 8–9): FBXL7, CTD-2350J17.1, MIR887, RNA5SP178, MARCHF11, MARCHF11-AS1, AC092335.1, NACAP6, LINC02150, AC020980.1, ZNF622, RETREG1, AC024588.1, AC022113.1, Y_RNA.
- chr5:31,093,977–31,595,669, 8 genes, copy number 10 (within-gene range 8–10): AC113386.1, CDH6, DUX4L51, DROSHA, Y_RNA, C5orf22, AC022417.1, RNU6-363P.
- chr5:34,651,457–45,895,970, 185 genes, copy number 14–16 (broad region; genes not listed).
- chr6:18,120,440–18,468,870, 10 genes, copy number 11: NHLRC1, TPMT, KDM1B, DEK, Y_RNA, AL138825.1, RNU6-263P, DDX18P3, IMPDH1P9, RNF144B.
- chr6:106,360,717–107,133,170, 17 genes, copy number 9 (within-gene range 5–9): CRYBG1, Y_RNA, RNA5SP211, AL109920.1, Y_RNA, RTN4IP1, RNU6-527P, QRSL1, RPL21P65, LINC02526, LINC02532, RNU6-117P, MIR587, CD24, MTRES1, BEND3, RNU6-1299P.
- chr7:17,205,652–17,940,501, 7 genes, copy number 10 (within-gene range 6–10): Metazoa_SRP, AC019117.3, SNORA63, AC019117.2, AC019117.1, AC006482.1, SNX13.
- chr7:29,988,600–30,993,254, 36 genes, copy number 9 (within-gene range 6–9): FKBP14-AS1, FKBP14, PLEKHA8, AC007285.1, AC007036.4, AC007036.5, MTURN, AC007036.2, AC007036.3, RPS27P16, AC007036.1, ZNRF2, MIR550A1, MIR550B1, AC006978.2, AC006978.1, LINC01176, NOD1, AC006027.1, GGCT, AC005154.5, GARS1-DT, AC005154.2, AC005154.4, AC005154.1, AC005154.3, GARS1, CRHR2, INMT, AC006022.1, INMT-MINDY4, MINDY4, AC004691.1, AC004691.2, AQP1, GHRHR.
- chr9:2,621,787–10,830,308, 115 genes, copy number 9–16 (broad region; genes not listed).
- chr9:16,409,503–17,503,923, 11 genes, copy number 11 (within-gene range 8–11): BNC2, AL449983.1, AL450003.1, BNC2-AS1, LSM1P1, AL162725.2, AL358117.1, RN7SL720P, RPS29P33, AL162725.1, CNTLN.
- chr9:20,331,446–43,045,120, 518 genes, copy number 9 (broad region; genes not listed).
- chr10:77,587,049–77,793,176, 6 genes, copy number 9: RNA5SP321, AL731556.1, AL731556.2, RNU6-1266P, IMPDH1P5, AL450306.1.
- chr11:86,431,590–87,025,777, 16 genes, copy number 11: AP001831.1, PTP4A1P6, AP001148.1, ME3, AP003059.1, AP003059.2, PRSS23, MOB4P2, OR7E13P, AP000654.1, OR7E2P, AP001528.1, AP001528.2, FZD4, FZD4-DT, HNRNPCP8.
- chr11:121,292,681–121,633,763, 5 genes, copy number 12: SC5D, BMPR1AP2, AP002365.1, AP000977.1, SORL1.
- chr12:55,636,860–56,488,414, 76 genes, copy number 10 (broad region; genes not listed).
- chr14:67,581,955–67,816,590, 19 genes, copy number 9 (within-gene range 4–9): PIGH, AL132640.1, AL132640.2, AL132640.3, Y_RNA, ARG2, AL049779.4, VTI1B, COX7A2P1, RNA5SP386, AL049779.1, RDH11, RDH12, RN7SL369P, RPL21P9, ZFYVE26, AL049779.3, RN7SL213P, AL049779.2.
- chr15:60,215,537–60,479,160, 6 genes, copy number 11: AC037433.1, ANXA2, AC087385.1, AC087385.2, AC087385.3, ICE2.
- chr15:60,529,973–60,545,159, 1 gene, copy number 11 (within-gene range 6–11): AC107241.1.
- chr17:70,628,917–70,779,230, 2 genes, copy number 10: AC005771.1, AC007423.1.
- chr18:22,586,465–23,026,488, 10 genes, copy number 10: RPS4XP18, RNU6-1032P, AC090912.1, AC090912.2, RBBP8, AC090912.3, UBE2CP2, MIR4741, RN7SL745P, Y_RNA.
- chr20:34,516,414–36,270,918, 70 genes, copy number 9 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 5. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
